Somatic mutation profile of tumor specimen MP2PRT-PASFIF-TMP1-A (aliquot MP2PRT-PASFIF-TMP1-A-1-0-D-A79Q-36) from MP2PRT case MP2PRT-PASFIF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,085 days).
Specimen MP2PRT-PASFIF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a2bda544-954e-44ca-8e0b-55f1f651265e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASFIF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASFIF-NB1-A-1-0-D-A79Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e373909-fdff-43dc-86d4-f364c911ff65

The open-access MAF lists 13 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 1, In Frame Del 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FRY | c.6997G>A p.D2333N | Missense Mutation (SNP) | VAF 21/278 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs755355616; called by muse, mutect2
- LRP1B | c.4568G>A p.R1523H | Missense Mutation (SNP) | VAF 138/311 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67246937; called by muse, mutect2, varscan2
- LRRC69 | c.739G>A p.V247I | Missense Mutation (SNP) | VAF 175/346 reads (51%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs200284658; called by muse, mutect2, varscan2
- OTOGL | c.6433C>A p.L2145M (on ENST00000547103; = p.L2136M on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 94/260 reads (36%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.904); catalogued as COSV54020275; called by muse, mutect2, varscan2
- PRDM9 | c.1097G>T p.G366V | Missense Mutation (SNP) | VAF 198/430 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99691418; called by muse, mutect2, varscan2
- BCAS1 | c.1654T>C p.S552P | Missense Mutation (SNP) | VAF 158/383 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC168 | c.13798T>C p.W4600R | Missense Mutation (SNP) | VAF 26/466 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.023); called by muse, mutect2
- DDX60L | c.1307A>G p.E436G | Missense Mutation (SNP) | VAF 99/235 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- IGKV1OR2-108 | c.351_353del p.P117del | In Frame Del (DEL) | VAF 37/149 reads (25%) | called by pindel*, varscan2
- KCNA7 | c.582_583insA p.Q195Tfs*13 | Frame Shift Ins (INS) | VAF 155/321 reads (48%) | called by mutect2, pindel*, varscan2*
- TCF12 | c.509A>T p.H170L | Missense Mutation (SNP) | VAF 149/304 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- AFF3 | c.276C>T p.L92= | Silent (SNP) | VAF 203/439 reads (46%) | catalogued as rs368156440; called by muse, varscan2
- CPLANE1 | c.*2284A>G | 3'UTR (SNP) | VAF 168/381 reads (44%) | called by muse, mutect2, varscan2
